Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8486, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8486-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted] Case ID	Gross Description	Microscopic Description	Diagnosis Details
[Redacted]			

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Fundus Tumor size: 5 x 4 x 3 cm Tumor features: Exophytic (polypoid) Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Submucosa Lymph nodes: 0/5 positive for metastasis (Regional 0/5) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

	ID

[page 3 of 3]
Excision date	Laterality

Source: NCI Genomic Data Commons file 95d66ea4-b634-40cf-a24d-3c87367a1490 (TCGA-BR-8486.0FDEE0D8-68A9-4820-9876-F0F4D6E1250C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).